Somatic mutation profile of tumor specimen TCGA-DF-A2KV-01A (aliquot TCGA-DF-A2KV-01A-11D-A17W-09) from TCGA case TCGA-DF-A2KV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 55.2 years (20,160 days).
Specimen TCGA-DF-A2KV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64b2ecd7-37c9-4152-b3a6-ceb7616fdb15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DF-A2KV-10A (Blood Derived Normal), aliquot TCGA-DF-A2KV-10A-01D-A17W-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9b759173-4773-4ec6-9fad-afdb502d48d7

The open-access MAF lists 1,486 somatic variants for this specimen: 1,187 protein-altering or splice-affecting, 261 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 990, Silent 261, Nonsense Mutation 166, Splice Site 18, Intron 17, Splice Region 8, RNA 7, 5'UTR 4, 3'UTR 4, 5'Flank 4, Frame Shift Ins 3, 3'Flank 2.

Variants (750 of 1,486; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP3B1 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 11/31 reads (35%) | catalogued as rs121908907, CM020265, COSV99672601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 6/29 reads (21%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- ARID1A | c.5965C>T p.R1989* | Nonsense Mutation (SNP) | VAF 10/43 reads (23%) | hotspot (GDC flag); catalogued as rs879255270, CM1311944, COSV61370535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DIS3 | c.2066G>A p.R689Q | Missense Mutation (SNP) | VAF 4/38 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV66706044; called by muse, mutect2
- HDAC8 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as rs397515415, CM128296, COSV65238373; ClinVar: pathogenic; called by muse, mutect2, varscan2
- IVD | c.1192C>T p.R398* (on ENST00000651168; = p.R395* on NM_002225.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/94 reads (22%) | catalogued as rs398123681, COSV51098904; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5395G>A p.E1799K | Missense Mutation (SNP) | VAF 22/50 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.08); PolyPhen possibly damaging (0.463); catalogued as rs863225264, CM156279, COSV63869964; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- NEK9 | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 6/15 reads (40%) | catalogued as rs901508820, COSV99464595; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- OCA2 | c.1922C>T p.S641L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868238523, COSV62337400, COSV62339851, COSV62344458; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PHF8 | c.739C>T p.R247* (on ENST00000357988 / NM_001184896.1; = p.R211* on NM_015107.3) | Nonsense Mutation (SNP) | VAF 7/62 reads (11%) | catalogued as rs121918522, CM054064, COSV57683731; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV55874903, COSV99836298; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 11/51 reads (22%) | catalogued as rs1554890335, COSV64288471, COSV64291810; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.654C>A p.C218* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as rs1554825165, CM128489, COSV64288514, COSV64302282; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SLC7A7 | c.753G>T p.E251D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs386833824, CM080558, COSV99591877; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SRCAP | c.8242C>T p.R2748* | Nonsense Mutation (SNP) | VAF 13/48 reads (27%) | catalogued as rs1085307899, CM136744, COSV52668892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 4/39 reads (10%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by mutect2, varscan2
- A1CF | c.1437C>A p.F479L (on ENST00000373993 / NM_138932.2; = p.F471L on NM_014576.4) | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.123); catalogued as COSV50959314; called by muse, mutect2, varscan2
- A3GALT2 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.885); catalogued as COSV100378242; called by muse, mutect2, varscan2
- ABCA13 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1250802648, COSV101330199, COSV70026114; called by muse, mutect2, varscan2
- ABCA13 | c.14042G>A p.R4681Q | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763955784, COSV68945809; called by muse, mutect2, varscan2
- ABCA6 | c.2383G>A p.E795K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs374410367; called by muse, mutect2, varscan2
- ABCB7 | c.1922C>T p.S641L (on ENST00000373394 / NM_001271696.3; = p.S642L on NM_004299.6) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1002483499, COSV99504453; called by muse, mutect2, varscan2
- ABCC12 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs535899598, COSV100252229; called by muse, mutect2
- ABCF1 | c.1945G>A p.D649N (on ENST00000326195 / NM_001025091.2; = p.D611N on NM_001090.3) | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.581); catalogued as rs776446823, COSV100400898; called by muse, mutect2, varscan2
- ABCG5 | c.1010A>C p.K337T | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV99575691; called by muse, mutect2, varscan2
- ABLIM1 | c.279G>T p.E93D | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV99522838; called by muse, mutect2, varscan2
- AC004593.2 | c.1148C>T p.S383L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs1169216156, COSV56090056; called by muse, mutect2
- AC024598.1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.067); catalogued as rs371278525, COSV60824183; called by muse, mutect2, varscan2
- AC093155.3 | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs892465103, COSV63350967; called by muse, mutect2, varscan2
- ACAD10 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.761); catalogued as rs750824318, COSV58158834; called by muse, mutect2, varscan2
- ACADSB | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as rs1266747835, COSV62550543; called by muse, varscan2
- ACBD5 | c.669G>T p.K223N (on ENST00000375888 / NM_001352568.1; = p.K214N on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV101022699; called by muse, mutect2, varscan2
- ACER3 | c.254A>C p.K85T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV99569003; called by muse, mutect2, varscan2
- ACOT9 | c.1024G>T p.D342Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100321485; called by muse, mutect2, varscan2
- ACOX3 | c.1839C>A p.F613L | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as rs760860897, COSV100712068; called by muse, mutect2
- ACOXL | c.1362T>G p.I454M (on ENST00000389811 / NM_001371254.1; = p.I424M on NM_001142807.4) | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.1); catalogued as COSV101096115; called by muse, mutect2, varscan2
- ACTBL2 | c.871C>T p.R291C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs888995937, COSV70661511; called by muse, mutect2, varscan2
- ADAM9 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as rs990954699, COSV101166311, COSV65962805; called by muse, mutect2, varscan2
- ADAMTS10 | c.942C>A p.F314L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54360583, COSV99547518; called by muse, mutect2, varscan2
- ADAMTS3 | c.3557A>C p.K1186T | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs1386743306, COSV99712264; called by muse, mutect2, varscan2
- ADGRF4 | c.1184C>T p.S395L | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs775954938, COSV51950767; called by muse, mutect2, varscan2
- ADGRG2 | c.2711A>C p.N904T (on ENST00000379869 / NM_001079858.3; = p.N901T on NM_005756.4) | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV100492789; called by muse, mutect2, varscan2
- ADGRG6 | c.3479C>A p.S1160Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99749058; called by muse, mutect2, varscan2
- ADGRV1 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758626904, COSV67981148; called by muse, mutect2, varscan2
- ADNP2 | c.490A>G p.N164D | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.96); PolyPhen benign (0.014); catalogued as COSV100081262; called by muse, mutect2, varscan2
- ADPGK | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374477325; called by muse, mutect2, varscan2
- AFF2 | c.849A>C p.Q283H | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651368; called by muse, mutect2, varscan2
- AGK | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100814737; called by muse, mutect2, varscan2
- AGMO | c.513+1G>T p.X171_splice | Splice Site (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100694857; called by muse, mutect2, varscan2
- AGPAT3 | c.1122A>C p.K374N | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as COSV99377877; called by muse, mutect2, varscan2
- AHCYL2 | c.1464G>A p.A488= | Splice Region (SNP) | VAF 10/32 reads (31%) | catalogued as rs771428608, COSV100273796; called by muse, mutect2, varscan2
- AHNAK | c.11869C>T p.P3957S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV99949969; called by muse, mutect2, varscan2
- AHR | c.346G>T p.E116* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99620355; called by mutect2, varscan2
- AK7 | c.1408T>G p.S470A | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99967605; called by muse, mutect2, varscan2
- AKAP12 | c.4268C>T p.A1423V | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.29); PolyPhen benign (0.022); catalogued as rs1269478109, COSV53573329, COSV53576009; called by muse, mutect2, varscan2
- AKAP6 | c.5778G>T p.E1926D | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as COSV99805037; called by muse, mutect2, varscan2
- AKAP9 | c.1952A>C p.N651T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV100663267; called by muse, mutect2, varscan2
- ALCAM | c.450G>T p.Q150H | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); catalogued as COSV100065892; called by muse, mutect2, varscan2
- ALDH1A2 | c.774G>T p.K258N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51094313; called by muse, mutect2, varscan2
- ALDH4A1 | c.1688A>G p.Q563R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99312471; called by muse, mutect2, varscan2
- ALG13 | c.441A>C p.Q147H | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV99323199; called by muse, mutect2, varscan2
- ALG8 | c.685C>T p.R229* | Nonsense Mutation (SNP) | VAF 13/32 reads (41%) | catalogued as rs533704173, COSV55202191, COSV55202506; called by muse, mutect2, varscan2
- ALOX5 | c.1999C>T p.R667W | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs780844866, COSV100980189; called by muse, mutect2, varscan2
- ALPI | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs903671931, COSV55013859; called by muse, mutect2, varscan2
- AMHR2 | c.1257G>T p.E419D | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99143675; called by muse, mutect2, varscan2
- AMOTL1 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); catalogued as COSV54414299; called by muse, mutect2, varscan2
- AMY2A | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 29/357 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV101340686, COSV70214852; called by muse, mutect2
- ANGPTL4 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.029); catalogued as rs557133449, COSV56844285; called by muse, mutect2, varscan2
- ANK1 | c.4906G>A p.D1636N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.3); catalogued as rs757733100, COSV99227134; called by muse, mutect2, varscan2
- ANK2 | c.3827T>G p.I1276S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100004573; called by muse, mutect2, varscan2
- ANKRD13B | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs781448930, COSV101198967; called by muse, mutect2, varscan2
- ANKRD30A | c.749T>G p.F250C (on ENST00000611781; = p.F194C on NM_052997.2) | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.224); catalogued as COSV100654549; called by muse, mutect2, varscan2
- ANKZF1 | c.167G>A p.S56N | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99850956; called by muse, mutect2, varscan2
- ANLN | c.2182A>C p.N728H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99732980; called by muse, mutect2, varscan2
- ANO5 | c.2658G>T p.E886D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV100201294; called by muse, mutect2, varscan2
- ANPEP | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.684); catalogued as rs147889608; called by muse, mutect2, varscan2
- AOPEP | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as rs1210104283, COSV99469608; called by muse, mutect2, varscan2
- AP002512.3 | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.39); catalogued as rs1326016320, COSV56565765; called by muse, mutect2
- AP3B1 | c.2734C>T p.R912* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as rs752519227, COSV54877147; called by muse, mutect2, varscan2
- AP3M2 | c.422G>A p.R141Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.223); catalogued as rs756052697, COSV51529483; called by mutect2, varscan2
- APAF1 | c.3163A>G p.N1055D (on ENST00000551964 / NM_181861.2; = p.N1001D on NM_001160.3) | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as COSV100244480; called by muse, mutect2, varscan2
- APOB | c.11504T>G p.I3835S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99268531; called by muse, mutect2, varscan2
- APOBEC1 | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57549020, COSV57550510; called by muse, mutect2, varscan2
- APOL5 | c.95T>C p.V32A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); catalogued as COSV99968489; called by muse, mutect2, varscan2
- ARHGAP21 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs764367717, COSV100256764; called by muse, mutect2, varscan2
- ARHGAP28 | c.1052T>C p.L351S (on ENST00000383472 / NM_001366230.1; = p.L192S on NM_001010000.3) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV99151593; called by muse, mutect2, varscan2
- ARHGEF25 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs61935728, COSV54088483; called by muse, mutect2, varscan2
- ARHGEF4 | c.1555C>T p.R519* | Nonsense Mutation (SNP) | VAF 19/42 reads (45%) | catalogued as COSV58125158; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV63438086, COSV63438570; called by muse, mutect2, varscan2
- ARNT | c.174A>C p.K58N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100590933, COSV100591430; called by muse, mutect2, varscan2
- ARX | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.043); catalogued as COSV100984093; called by muse, mutect2
- ASL | c.656-1G>T p.X219_splice | Splice Site (SNP) | VAF 4/24 reads (17%) | catalogued as CS073434, COSV59190029; called by muse, mutect2, varscan2
- ATL3 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV100219735; called by muse, mutect2, varscan2
- ATP11C | c.149C>A p.S50* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100558779, COSV59563623; called by muse, mutect2, varscan2
- ATP13A4 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 13/33 reads (39%) | catalogued as COSV99795341; called by muse, mutect2, varscan2
- ATP2B4 | c.110C>T p.S37L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs986432272, COSV100398125; called by muse, mutect2, varscan2
- ATP6V1A | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1351534048, COSV99850458; called by muse, mutect2, varscan2
- ATP6V1B1 | c.932T>G p.V311G | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99314564; called by muse, mutect2, varscan2
- ATP6V1C2 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs771576322, COSV55360958; called by muse, mutect2, varscan2
- ATP7A | c.3479C>T p.S1160L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs149576827, COSV58450181; called by muse, mutect2, varscan2
- ATP9A | c.1789C>T p.R597W | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759463694, COSV100125718; called by muse, mutect2, varscan2
- ATRNL1 | c.1816G>T p.D606Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100747094; called by muse, mutect2, varscan2
- ATRX | c.5868G>T p.K1956N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.293); catalogued as COSV100971562; called by muse, mutect2, varscan2
- ATRX | c.3249G>T p.K1083N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV100971564; called by muse, mutect2, varscan2
- AWAT2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 16/29 reads (55%) | catalogued as COSV52142874; called by muse, mutect2, varscan2
- AXL | c.1325C>A p.S442* (on ENST00000301178 / NM_021913.5; = p.S433* on NM_001699.6) | Nonsense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV99997380; called by muse, mutect2
- BACE2 | c.285G>T p.E95D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.569); catalogued as COSV100161237; called by muse, mutect2, varscan2
- BAZ2B | c.2819T>G p.I940S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV99681090; called by muse, mutect2, varscan2
- BCLAF1 | c.2029G>T p.E677* | Nonsense Mutation (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99219577; called by muse, mutect2, varscan2
- BCLAF3 | c.1346A>G p.N449S | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs778265951, COSV100503424; called by muse, mutect2, varscan2
- BIRC2 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV99926950; called by muse, mutect2, varscan2
- BLZF1 | c.941T>C p.V314A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.114); catalogued as COSV100250864; called by muse, mutect2, varscan2
- BMX | c.372C>A p.F124L | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100564501; called by muse, mutect2, varscan2
- BOC | c.1561G>A p.D521N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs780171292, COSV56353654; called by muse, mutect2, varscan2
- BOD1L1 | c.6451G>T p.E2151* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as COSV99240555; called by muse, mutect2, varscan2
- BOLL | c.266T>G p.I89S | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99987490; called by muse, mutect2, varscan2
- BRD9 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.541); catalogued as rs1310438283, COSV100057671; called by muse, mutect2, varscan2
- BRDT | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV100746613; called by muse, mutect2, varscan2
- BSN | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs188067365, COSV99610035; called by muse, mutect2, varscan2
- BTAF1 | c.3184G>A p.D1062N | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs758122724, COSV99795913; called by muse, mutect2, varscan2
- BTBD11 | c.2707G>T p.E903* (on ENST00000280758 / NM_001018072.2; = p.E440* on NM_001017523.2) | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99777139; called by muse, mutect2, varscan2
- C12orf4 | c.908G>T p.R303I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.664); catalogued as COSV54206233; called by muse, mutect2, varscan2
- C12orf4 | c.40G>T p.E14* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | catalogued as rs758466065, COSV54206411; called by muse, mutect2, varscan2
- C18orf54 | c.214A>C p.K72Q | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV100266734; called by muse, mutect2
- C1orf112 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV53680954; called by muse, mutect2, varscan2
- C1orf194 | c.337G>T p.E113* (on ENST00000369948 / NM_001245025.3; = p.E101* on NM_001122961.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 12/51 reads (24%) | catalogued as rs763816794, COSV64049816; called by muse, mutect2, varscan2
- C1orf50 | c.407C>A p.S136Y | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100998157; called by muse, mutect2
- C1orf87 | c.1057T>G p.L353V | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100967278; called by muse, mutect2, varscan2
- C2 | c.2032G>T p.E678* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV100190551, COSV100191548; called by muse, mutect2, varscan2
- C2orf16 | c.1806A>C p.K602N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV100821093; called by muse, mutect2, varscan2
- C2orf16 | c.2337G>T p.E779D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as COSV100821094; called by muse, mutect2
- C2orf49 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99307673; called by muse, mutect2, varscan2
- C3 | c.86T>C p.I29T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV99837371; called by muse, mutect2, varscan2
- C4orf3 | c.107C>A p.A36E | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.368); catalogued as COSV101208179; called by muse, mutect2, varscan2
- C6 | c.2521C>T p.R841C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs187593836, COSV54712421; called by muse, varscan2
- C6 | c.852T>G p.F284L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99667922; called by muse, mutect2, varscan2
- CACNA1A | c.427A>C p.I143L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100803366; called by muse, mutect2, varscan2
- CACNA1D | c.1222G>T p.E408* | Nonsense Mutation (SNP) | VAF 15/45 reads (33%) | catalogued as COSV55452044; called by muse, mutect2, varscan2
- CACNA1F | c.4822G>A p.D1608N | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV59905707; called by muse, mutect2, varscan2
- CACNA2D4 | c.15C>A p.C5* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99766271; called by muse, mutect2, varscan2
- CACNB2 | c.780G>T p.E260D (on ENST00000324631 / NM_201596.3; = p.E205D on NM_000724.4) | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as COSV99996748; called by muse, mutect2, varscan2
- CACNB2 | c.1094C>A p.A365E (on ENST00000324631 / NM_201596.3; = p.A310E on NM_000724.4) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99996750; called by muse, mutect2, varscan2
- CADPS | c.2474T>G p.I825S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV99341323; called by muse, mutect2, varscan2
- CALCOCO1 | c.1036C>T p.R346* | Nonsense Mutation (SNP) | VAF 15/44 reads (34%) | catalogued as COSV100017230; called by muse, mutect2, varscan2
- CALHM6 | c.722T>G p.F241C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100889479; called by muse, mutect2, varscan2
- CALR3 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV99522383; called by muse, mutect2, varscan2
- CAMTA2 | c.3278T>G p.L1093R | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99236869; called by muse, mutect2
- CAPN10 | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs760362038, COSV54376964; called by muse, mutect2, varscan2
- CARD18 | c.215T>G p.F72C | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0.101); catalogued as COSV101596040, COSV73233128; called by muse, mutect2, varscan2
- CARD6 | c.1612A>C p.S538R | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV99621400; called by muse, mutect2
- CASKIN1 | c.889G>A p.D297N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58872301; called by muse, mutect2, varscan2
- CATSPER1 | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100376290; called by muse, mutect2, varscan2
- CCDC112 | c.298G>T p.E100* | Nonsense Mutation (SNP) | VAF 7/20 reads (35%) | catalogued as COSV101100551; called by muse, mutect2, varscan2
- CCDC144A | c.2541G>T p.K847N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs765016740, COSV100138749; called by muse, mutect2, varscan2
- CCDC146 | c.1465G>T p.E489* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as rs758101331, COSV53543643, COSV53551611; called by muse, mutect2, varscan2
- CCDC150 | c.820G>T p.E274* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99777446; called by muse, mutect2, varscan2
- CCDC18 | c.2782T>G p.L928V (on ENST00000343253 / NM_001306076.1; = p.L929V on NM_206886.4) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV100160033; called by muse, mutect2, varscan2
- CCDC186 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as rs532080412, COSV100990995, COSV65159686; called by muse, mutect2, varscan2
- CCDC191 | c.1948C>T p.Q650* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV99878611; called by muse, mutect2, varscan2
- CCDC39 | c.1714C>T p.R572* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs1348126553, CM110032, COSV56486444, COSV99870843; called by muse, mutect2, varscan2
- CCDC39 | c.726T>A p.D242E | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.251); catalogued as COSV99870847; called by muse, mutect2, varscan2
- CCDC69 | c.259C>T p.R87* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as rs114476897; called by muse, mutect2, varscan2
- CCDC74B | c.587C>A p.S196* | Nonsense Mutation (SNP) | VAF 13/97 reads (13%) | catalogued as COSV100134789, COSV60100611; called by muse, mutect2, varscan2
- CCL5 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs571565063; called by muse, mutect2, varscan2
- CCN6 | c.445G>A p.A149T | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV100037234; called by muse, mutect2, varscan2
- CCNB1IP1 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs1385967366, COSV100738498; called by muse, mutect2, varscan2
- CCNB2 | c.766G>T p.E256* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV55595159; called by muse, mutect2, varscan2
- CCNB3 | c.633G>T p.M211I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs1450379306, COSV99329995; called by muse, mutect2, varscan2
- CCNB3 | c.3423+1G>A p.X1141_splice | Splice Site (SNP) | VAF 5/27 reads (19%) | catalogued as COSV99329996; called by muse, mutect2, varscan2
- CCNC | c.846A>C p.Q282H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.205); catalogued as COSV100412720; called by muse, mutect2, varscan2
- CD109 | c.2544G>T p.M848I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs527475108, COSV99754804; called by muse, mutect2
- CD163 | c.2158C>T p.R720C | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765869382, COSV63136320; called by muse, mutect2, varscan2
- CD163L1 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs769098820, COSV58019485; called by muse, mutect2, varscan2
- CD163L1 | c.136T>G p.L46V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs758879274, COSV100550775; called by muse, mutect2, varscan2
- CD1B | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as COSV100939318; called by muse, mutect2, varscan2
- CD209 | c.348G>T p.E116D | Missense Mutation (SNP) | VAF 41/134 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.771); catalogued as COSV99214213; called by muse, mutect2, varscan2
- CD22 | c.2297G>A p.R766H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.119); catalogued as rs202049039, COSV99323844; called by muse, mutect2, varscan2
- CD244 | c.842G>T p.R281I (on ENST00000368033 / NM_001166663.2; = p.R276I on NM_016382.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV100458939, COSV59239525; called by muse, mutect2, varscan2
- CD33 | c.756G>T p.E252D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.087); catalogued as COSV99220857; called by muse, mutect2, varscan2
- CD84 | c.486G>T p.K162N | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV60867365; called by muse, mutect2, varscan2
- CD96 | c.1403C>T p.S468L (on ENST00000283285 / NM_198196.3; = p.S452L on NM_005816.5) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs749352877, COSV99343684; called by muse, mutect2, varscan2
- CDC40 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | catalogued as COSV100309604; called by muse, mutect2, varscan2
- CDH1 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.072); catalogued as rs780759537, COSV55730065; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH12 | c.518C>A p.S173Y | Missense Mutation (SNP) | VAF 48/179 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101203417; called by muse, mutect2, varscan2
- CDH8 | c.1644G>T p.K548N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV100184438, COSV54861232; called by muse, mutect2, varscan2
- CDK13 | c.2770G>T p.E924* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV99474834; called by mutect2, varscan2
- CDK5 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 5/19 reads (26%) | catalogued as rs1196471483; called by muse, mutect2
- CDON | c.3729G>T p.E1243D (on ENST00000392693 / NM_001243597.2; = p.E1220D on NM_016952.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.01); catalogued as COSV99702079; called by muse, mutect2, varscan2
- CEP112 | c.2554A>C p.K852Q (on ENST00000392769 / NM_001353127.1; = p.K108Q on NM_001037325.3) | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.047); catalogued as COSV58067336; called by muse, mutect2, varscan2
- CEP112 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as rs749739430, COSV101211205; called by muse, mutect2, varscan2
- CEP350 | c.2916A>C p.K972N | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.388); catalogued as COSV100855377; called by muse, mutect2, varscan2
- CEP83 | c.1534A>C p.N512H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV100353310; called by muse, mutect2, varscan2
- CFAP70 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60282124; called by muse, mutect2, varscan2
- CFAP94 | c.610A>C p.K204Q (on ENST00000320267 / NM_001352064.2; = p.K210Q on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.312); catalogued as COSV100209799; called by muse, mutect2, varscan2
- CFHR1 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.663); catalogued as rs750324699, COSV57628469; called by muse, mutect2, varscan2
- CHCHD4 | c.32G>A p.R11Q (on ENST00000396914 / NM_001098502.2; = p.R24Q on NM_144636.3) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs755009391, COSV55499938; called by muse, mutect2, varscan2
- CHD3 | c.2582C>T p.S861L | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57872876; called by muse, mutect2, varscan2
- CHL1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs150837773; called by muse, mutect2, varscan2
- CHMP5 | c.425C>G p.A142G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.792); catalogued as COSV99794695; called by muse, mutect2, varscan2
- CHST15 | c.1087G>A p.D363N | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.421); catalogued as rs1040064513, COSV60564116; called by muse, mutect2, varscan2
- CHST9 | c.15A>C p.E5D | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.007); catalogued as COSV99411085; called by muse, mutect2, varscan2
- CHSY3 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs150490435, COSV100520123; called by muse, mutect2, varscan2
- CIP2A | c.2439A>C p.E813D | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.013); catalogued as rs150636922, COSV99843213; called by muse, mutect2, varscan2
- CLCN7 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.523); catalogued as COSV99247708; called by muse, mutect2, varscan2
- CLDN25 | c.329T>G p.I110S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as COSV101493618; called by muse, mutect2, varscan2
- CLEC4E | c.373-1G>T p.X125_splice | Splice Site (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100222768; called by muse, mutect2, varscan2
- CLEC4E | c.279C>A p.F93L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.011); catalogued as COSV55225062; called by muse, mutect2, varscan2
- CLSPN | c.942T>G p.I314M | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as COSV99231639; called by muse, mutect2, varscan2
- CLVS2 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.363); catalogued as rs1419990746, COSV99253461, COSV99253683; called by muse, mutect2, varscan2
- CMYA5 | c.701C>T p.S234L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs374313124, COSV71409406; called by muse, mutect2, varscan2
- CMYA5 | c.4489C>A p.L1497I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.017); catalogued as rs1225876966, COSV71404227; called by muse, mutect2, varscan2
- CNOT10 | c.1061G>A p.R354K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.444); catalogued as COSV100095174; called by muse, mutect2, varscan2
- CNOT11 | c.516A>C p.G172= | Splice Region (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99179397; called by muse, mutect2, varscan2
- CNTN3 | c.2002T>C p.W668R | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99726287; called by muse, mutect2, varscan2
- CNTN6 | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as rs1176820262, COSV63167984, COSV63170441; called by muse, mutect2, varscan2
- CNTNAP3 | c.3710T>C p.V1237A | Missense Mutation (SNP) | VAF 98/640 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99905763; called by muse, mutect2, varscan2
- CNTNAP5 | c.311C>T p.T104M | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs775431778, COSV101444320; called by muse, mutect2, varscan2
- CNTNAP5 | c.3173C>A p.S1058Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.361); catalogued as COSV101444321; called by muse, mutect2, varscan2
- COCH | c.369A>C p.E123D (on ENST00000216361 / NM_001347720.1; = p.E58D on NM_004086.3) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV99363980; called by muse, mutect2, varscan2
- COG6 | c.718G>T p.E240* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV100743449; called by muse, mutect2, varscan2
- COL11A2 | c.247G>T p.D83Y | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59495501; called by muse, mutect2, varscan2
- COL12A1 | c.3092G>A p.R1031H | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.883); catalogued as rs752304678, COSV59405578; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL20A1 | c.2079C>T p.I693= | Splice Region (SNP) | VAF 10/36 reads (28%) | catalogued as COSV100491630; called by muse, mutect2, varscan2
- COL25A1 | c.1852C>T p.R618C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779859944, COSV101211692; called by muse, mutect2, varscan2
- COL4A4 | c.3706+2T>C p.X1236_splice | Splice Site (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100307897; called by muse, mutect2, varscan2
- COL4A4 | c.2077C>T p.P693S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs572923977, COSV61630879; called by muse, varscan2
- COL7A1 | c.8417G>A p.G2806D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1439137820, COSV99866451; called by muse, mutect2, varscan2
- COL7A1 | c.2044C>T p.R682* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs1262422383, CM992837, COSV100097898; called by muse, mutect2, varscan2
- COPA | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.018); catalogued as rs767163438, COSV54106015; called by muse, mutect2, varscan2
- COPS8 | c.241A>C p.I81L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV100585482; called by muse, mutect2, varscan2
- COPZ2 | c.614A>C p.K205T | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV99133909; called by muse, mutect2, varscan2
- CPA3 | c.1021C>T p.R341* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as rs779939415, COSV99936546; called by muse, mutect2, varscan2
- CPEB4 | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1466318069, COSV54172592; called by muse, mutect2, varscan2
- CPNE2 | c.67G>A p.V23M | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as rs771489237, COSV51960904, COSV99321388; called by muse, mutect2, varscan2
- CRY1 | c.1228T>G p.F410V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.025); catalogued as COSV99151091; called by muse, mutect2, varscan2
- CSAG1 | c.176G>T p.R59I | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV100767516; called by muse, mutect2
- CSE1L | c.701A>C p.N234T | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99522314; called by muse, mutect2, varscan2
- CSHL1 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99368298; called by muse, mutect2, varscan2
- CSMD2 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.136); catalogued as rs1425116736, COSV99596263; called by muse, mutect2, varscan2
- CSNK2A1 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 5/51 reads (10%) | catalogued as rs1380843831, COSV53934311; called by muse, mutect2, varscan2
- CTAGE1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs1333081479, COSV66943323; called by muse, mutect2, varscan2
- CTAGE6 | c.1377G>T p.E459D | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV101417790; called by muse, mutect2, varscan2
- CTAGE6 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 37/284 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs779951636, COSV69916572, COSV69917874; called by muse, mutect2, varscan2
- CTCF | c.1106A>G p.H369R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99866755; called by muse, mutect2, varscan2
- CTLA4 | c.529T>G p.Y177D | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55591755, COSV99865490; called by muse, mutect2, varscan2
- CTNND1 | c.1382G>A p.R461Q | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs751657184, COSV62383044; called by muse, mutect2, varscan2
- CTXN3 | c.62C>T p.S21F | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101060707, COSV65218087; called by muse, mutect2, varscan2
- CYLC1 | c.822G>T p.K274N | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs148140928, COSV100255030, COSV61413473; called by muse, mutect2, varscan2
- CYSLTR1 | c.667A>C p.K223Q | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.372); catalogued as COSV100964764; called by muse, mutect2, varscan2
- DAPK3 | c.241G>A p.D81N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs960961126, COSV100009929; called by muse, mutect2, varscan2
- DCAF10 | c.1429G>T p.E477* | Nonsense Mutation (SNP) | VAF 27/95 reads (28%) | catalogued as COSV99647957; called by muse, mutect2, varscan2
- DCAF12 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV63512057; called by muse, mutect2, varscan2
- DCAF13 | c.468+1G>A p.X156_splice | Splice Site (SNP) | VAF 6/11 reads (55%) | catalogued as COSV52574939; called by muse, mutect2, varscan2
- DCAF4 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.179); catalogued as rs766596013, COSV100611195; called by muse, mutect2, varscan2
- DCAF4L2 | c.386C>A p.S129Y | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV60477184, COSV60480639; called by muse, mutect2, varscan2
- DCAF8L1 | c.1403C>A p.S468* | Nonsense Mutation (SNP) | VAF 14/46 reads (30%) | catalogued as COSV101491567; called by muse, mutect2, varscan2
- DCC | c.863C>A p.S288Y | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV59113543; called by muse, mutect2, varscan2
- DCDC1 | c.3752A>G p.Y1251C (on ENST00000597505 / NM_001367979.1; = p.Y358C on NM_020869.3) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100338864; called by muse, mutect2
- DCHS1 | c.6805G>A p.D2269N | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55031393; called by muse, mutect2, varscan2
- DCLK3 | c.279G>T p.K93N | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV69362855; called by mutect2, varscan2
- DCP2 | c.970A>C p.K324Q | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV101203976; called by muse, mutect2, varscan2
- DCPS | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.487); catalogued as rs772776014, COSV55012087; called by muse, mutect2, varscan2
- DDR1 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.228); catalogued as COSV100242224; called by muse, mutect2, varscan2
- DDX10 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV100489936; called by muse, mutect2, varscan2
- DDX20 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100865977; called by muse, mutect2, varscan2
- DDX60L | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as rs866796514, COSV52717831; called by muse, mutect2, varscan2
- DENND4C | c.4665A>C p.E1555D (on ENST00000434457 / NM_001330640.2; = p.E1506D on NM_017925.7) | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100727633; called by muse, mutect2, varscan2
- DGAT2 | c.462G>T p.R154S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV99930039; called by muse, mutect2, varscan2
- DGKI | c.2545G>T p.E849* | Nonsense Mutation (SNP) | VAF 7/17 reads (41%) | catalogued as COSV99937659; called by muse, mutect2, varscan2
- DGKK | c.582G>T p.K194N | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV101053241; called by muse, varscan2
- DHCR24 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs200217334; called by muse, mutect2, varscan2
- DHX29 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.849); catalogued as COSV99286969; called by muse, mutect2, varscan2
- DIAPH1 | c.2514G>T p.K838N | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.911); catalogued as rs761209182, COSV53883958; called by muse, mutect2, varscan2
- DICER1 | c.840T>G p.F280L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.761); catalogued as COSV100602624; called by muse, mutect2, varscan2
- DLGAP1 | c.2162C>A p.S721* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100234328, COSV59783944; called by muse, mutect2, varscan2
- DMBT1 | c.3200C>A p.S1067Y (on ENST00000338354 / NM_001377530.1; = p.S568Y on NM_004406.3) | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV100354242; called by muse, mutect2
- DMKN | c.1224G>T p.W408C | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100304004; called by muse, mutect2, varscan2
- DMRT2 | c.1511G>A p.R504K | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as COSV99426299; called by muse, mutect2, varscan2
- DMXL2 | c.1106-1G>T p.X369_splice | Splice Site (SNP) | VAF 9/29 reads (31%) | catalogued as COSV51845082; called by muse, mutect2
- DNAH17 | c.5114C>T p.T1705M | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs189137994; called by muse, mutect2, varscan2
- DNAH17 | c.2482C>T p.R828C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.103); catalogued as rs777090859, COSV67751492; called by muse, mutect2, varscan2
- DNAH3 | c.10971C>A p.F3657L | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99771098; called by muse, mutect2, varscan2
- DNAH5 | c.13775G>A p.R4592Q | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367709427, COSV54253927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.2548C>T p.R850C | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs770192166, COSV56750804; called by muse, mutect2, varscan2
- DNAJB13 | c.456C>A p.F152L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.489); catalogued as COSV60270214; called by muse, mutect2, varscan2
- DNAJC2 | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99971469; called by muse, mutect2, varscan2
- DNAJC28 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | catalogued as rs138072076; called by muse, mutect2, varscan2
- DNAJC28 | c.131A>C p.K44T | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs529962153, COSV100074778; called by muse, mutect2, varscan2
- DNAJC5B | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs200440195, COSV52536291; called by muse, mutect2, varscan2
- DNTT | c.223G>T p.V75L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV100960786; called by muse, mutect2, varscan2
- DOCK10 | c.4867A>G p.I1623V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.228); catalogued as COSV99291995; called by muse, mutect2, varscan2
- DOCK11 | c.5770G>T p.D1924Y | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV99354935; called by muse, mutect2, varscan2
- DOCK4 | c.2356T>G p.L786V | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as COSV101448015; called by muse, mutect2, varscan2
- DOCK7 | c.6394C>T p.R2132* (on ENST00000635253 / NM_001367561.1; = p.R2101* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as COSV99226224; called by muse, mutect2, varscan2
- DOCK8 | c.5397C>A p.F1799L | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV101210075; called by muse, mutect2, varscan2
- DOP1A | c.3641C>T p.S1214F | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as COSV52719028; called by muse, mutect2, varscan2
- DOT1L | c.3597-1G>T p.X1199_splice | Splice Site (SNP) | VAF 4/34 reads (12%) | catalogued as COSV101288875; called by muse, mutect2, varscan2
- DSC3 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs372346117; called by muse, mutect2, varscan2
- DSCAM | c.1301C>A p.P434H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101261682; called by muse, mutect2, varscan2
- DSEL | c.3166C>A p.P1056T | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100026168; called by muse, mutect2, varscan2
- DSG1 | c.2023A>G p.T675A | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV99936644; called by muse, mutect2, varscan2
- DSG2 | c.1159C>A p.H387N | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV99853617; called by muse, mutect2, varscan2
- DST | c.4413C>A p.F1471L (on ENST00000361203 / NM_001374722.1; = p.F1145L on NM_015548.5) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.32); catalogued as COSV99760627; called by muse, mutect2, varscan2
- DYM | c.1597C>T p.R533* | Nonsense Mutation (SNP) | VAF 15/35 reads (43%) | catalogued as rs780873164, COSV53981860, COSV53991634; called by muse, mutect2, varscan2
- DYNC1LI2 | c.949G>T p.E317* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99263302; called by muse, mutect2, varscan2
- DYNC2H1 | c.4391T>C p.V1464A | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100519935; called by muse, mutect2, varscan2
- EFHB | c.1513A>G p.T505A | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.8); catalogued as rs778757513, COSV99860334; called by muse, mutect2, varscan2
- EGLN3 | c.36G>T p.E12D | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.033); catalogued as COSV99164417; called by muse, mutect2, varscan2
- EHHADH | c.1404G>T p.K468N | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99213394; called by muse, mutect2, varscan2
- EIF4A1 | c.997G>A p.A333T | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV51511160, COSV99549219; called by muse, mutect2, varscan2
- EIF4H | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV99733699; called by muse, mutect2, varscan2
- ELAVL1 | c.378C>A p.F126L | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV100688540; called by muse, mutect2
- ELF3 | c.1060T>G p.F354V | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100668951, COSV62838886; called by muse, mutect2
- EML1 | c.2225T>C p.I742T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV99215756; called by muse, mutect2, varscan2
- ENDOU | c.286G>A p.E96K (on ENST00000422538 / NM_001172439.2; = p.E55K on NM_006025.4) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs775147338, COSV99968398; called by muse, mutect2, varscan2
- ENPEP | c.1555T>G p.F519V | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99488229; called by muse, mutect2, varscan2
- ENPEP | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 6/52 reads (12%) | catalogued as COSV54456328, COSV99486839; called by muse, mutect2, varscan2
- ENPP5 | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57908129, COSV57909386; called by muse, mutect2, varscan2
- ENTPD3 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as COSV57193759, COSV57196762; called by muse, mutect2, varscan2
- ENTPD7 | c.1495A>C p.N499H | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.841); catalogued as COSV100978507; called by muse, mutect2, varscan2
- EP300 | c.3490T>C p.C1164R | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99610045; called by muse, mutect2, varscan2
- EPHA10 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.618); catalogued as rs548534668, COSV100361805; called by mutect2, varscan2
- EPHA5 | c.2113G>A p.A705T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56637364, COSV99901713; called by muse, mutect2, varscan2
- ERBB2 | c.1367G>A p.R456H | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99509317; called by muse, mutect2, varscan2
- ERBIN | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV99397969; called by muse, mutect2, varscan2
- ERCC6L | c.2077G>T p.E693* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as COSV57819254; called by muse, mutect2
- ERCC6L2 | c.2035T>C p.F679L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs1272883266, COSV99999054; called by muse, mutect2, varscan2
- ERMN | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 8/66 reads (12%) | catalogued as rs1469712056, COSV101263012, COSV68075619; called by muse, mutect2, varscan2
- ESRP1 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs771325567, COSV64412009; called by muse, mutect2, varscan2
- EXOC6 | c.2324T>G p.F775C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV99592609; called by muse, mutect2, varscan2
- EXTL1 | c.1748C>T p.T583I | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.145); catalogued as COSV100958635; called by muse, mutect2, varscan2
- F8 | c.3550G>T p.E1184* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100812072; called by muse, mutect2, varscan2
- FAM111B | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV100639377; called by muse, mutect2
- FAM135B | c.3171C>A p.F1057L | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV52739774; called by muse, mutect2, varscan2
- FAM135B | c.50T>G p.F17C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99358362; called by muse, mutect2, varscan2
- FAM155A | c.78G>T p.E26D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.49); PolyPhen benign (0.18); catalogued as rs1042324320, COSV65550109; called by muse, mutect2, varscan2
- FAM199X | c.447T>G p.S149R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as COSV100245578; called by muse, mutect2, varscan2
- FAM47B | c.1135A>C p.K379Q | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV100264690; called by muse, mutect2, varscan2
- FAM47C | c.1094C>A p.P365H | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.202); catalogued as rs372986772, COSV100792989; called by muse, mutect2, varscan2
- FAM9C | c.155C>A p.S52Y | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100452817, COSV100452921; called by muse, mutect2, varscan2
- FASTKD1 | c.173G>T p.R58I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV70006765; called by muse, mutect2, varscan2
- FAT1 | c.1262C>A p.S421Y | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.868); catalogued as COSV101499673; called by muse, mutect2, varscan2
- FAT2 | c.11425C>A p.L3809I | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.076); catalogued as COSV55814637, COSV55818269; called by muse, mutect2, varscan2
- FAT4 | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.99); catalogued as COSV67902260; called by muse, mutect2, varscan2
- FAT4 | c.2203C>T p.R735W | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as rs775165068, COSV67889091; called by muse, mutect2, varscan2
- FAT4 | c.5327C>T p.T1776I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100630445; called by muse, mutect2, varscan2
- FAT4 | c.10115C>A p.S3372Y | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100630447; called by muse, mutect2, varscan2
- FBLIM1 | c.600G>T p.M200I | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV100181876; called by muse, mutect2, varscan2
- FBP1 | c.898A>C p.K300Q | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.087); catalogued as COSV100941360; called by muse, mutect2, varscan2
- FBXO10 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs776126565, COSV52833356; called by muse, mutect2, varscan2
- FBXO21 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1001312539, COSV100401890; called by muse, mutect2, varscan2
- FCAR | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as rs375603668; called by muse, mutect2, varscan2
- FCRL4 | c.1346C>T p.S449L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.03); catalogued as rs777588327, COSV54863730; called by muse, mutect2, varscan2
- FCRLB | c.63G>T p.E21D | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV100396420; called by muse, mutect2, varscan2
- FDXACB1 | c.1641G>T p.K547N | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV52786681, COSV52789287; called by muse, mutect2, varscan2
- FER1L6 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs753364876, COSV67549608; called by muse, varscan2
- FEZ1 | c.191A>C p.N64T | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.87); catalogued as COSV99631285; called by muse, mutect2, varscan2
- FFAR2 | c.763C>T p.R255W | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1409706065, COSV55832400; called by muse, mutect2, varscan2
- FGF13 | c.104C>A p.S35Y | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as COSV101003642; called by muse, mutect2, varscan2
- FGF14 | c.456T>G p.N152K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101087892, COSV65946522; called by muse, mutect2, varscan2
- FGG | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as COSV100272118; called by mutect2, varscan2
- FILIP1 | c.3298G>A p.E1100K | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.343); catalogued as rs868698674, COSV52728473; called by muse, mutect2, varscan2
- FLT3 | c.563G>A p.S188N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.25); PolyPhen benign (0.076); catalogued as rs1363820822, COSV54056422, COSV99610415; called by muse, mutect2, varscan2
- FMNL3 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1206871083, COSV53303628; called by muse, mutect2, varscan2
- FMO4 | c.679T>C p.W227R | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100882181; called by muse, mutect2, varscan2
- FRAS1 | c.808C>T p.R270C | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs773283272, COSV53592068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FRMD3 | c.1681G>A p.E561K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.622); catalogued as rs753230861, COSV100171106; called by muse, mutect2, varscan2
- FRMPD2 | c.614G>T p.R205I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59716847; called by muse, mutect2, varscan2
- FRMPD3 | c.3114G>T p.K1038N | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99347221; called by muse, mutect2, varscan2
- FRMPD4 | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101044244; called by muse, mutect2, varscan2
- FRY | c.1249C>T p.R417* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as rs1229819218, COSV66569638; called by muse, mutect2, varscan2
- FTHL17 | c.352C>A p.L118M | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV100784318, COSV100784454; called by muse, mutect2, varscan2
- FUS | c.1154G>A p.G385D | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); catalogued as COSV99569073; called by muse, mutect2, varscan2
- FYB2 | c.1257A>C p.K419N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as COSV100599846; called by muse, mutect2, varscan2
- FZR1 | c.655G>A p.V219M | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100553937; called by muse, mutect2, varscan2
- G6PD | c.1439T>C p.I480T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.047); catalogued as COSV100855152; called by muse, mutect2
- GAB3 | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV100850713; called by muse, mutect2, varscan2
- GABBR1 | c.477G>T p.V159= | Splice Region (SNP) | VAF 21/55 reads (38%) | catalogued as COSV100590161; called by muse, mutect2, varscan2
- GABRA1 | c.1292T>G p.F431C | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99196335; called by muse, mutect2
- GABRG1 | c.138T>G p.D46E | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.237); catalogued as COSV99778852; called by muse, mutect2, varscan2
- GABRQ | c.1517C>T p.S506L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs201961702, COSV64783646; called by muse, mutect2, varscan2
- GALNS | c.581T>G p.F194C | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV51936276; called by muse, mutect2, varscan2
- GALNT14 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.56); catalogued as rs1045023, COSV100204265; called by muse, mutect2, varscan2
- GALNT8 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.141); catalogued as COSV99363313; called by muse, mutect2, varscan2
- GALR1 | c.726G>T p.K242N | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV100231867; called by muse, mutect2, varscan2
- GATA1 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.216); catalogued as rs1418790540, COSV100936773; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBF1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV100890708; called by muse, mutect2, varscan2
- GBP1 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.158); catalogued as rs774147151; called by mutect2, varscan2
- GBP5 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 54/164 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.749); catalogued as rs755832842, COSV58591871; called by muse, mutect2, varscan2
- GBP7 | c.1201G>T p.A401S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.432); catalogued as COSV99643569; called by muse, mutect2, varscan2
- GFM2 | c.207-1G>T p.X69_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99714752; called by muse, mutect2, varscan2
- GID8 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV56611279, COSV56611484; called by muse, mutect2, varscan2
- GIGYF1 | c.277T>G p.S93A | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV99310130; called by muse, mutect2, varscan2
- GINS1 | c.512A>T p.K171I | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99320282; called by muse, mutect2
- GJA10 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as rs150298953; called by muse, mutect2, varscan2
- GK | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV66734180; called by muse, mutect2, varscan2
- GNA14 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.342); catalogued as rs767780053, COSV100503443; called by muse, varscan2
- GNA14 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.172); catalogued as COSV100503445; called by muse, varscan2
- GNL3 | c.1082C>A p.S361Y | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.756); catalogued as COSV99804142; called by muse, mutect2, varscan2
- GOLIM4 | c.1757A>T p.K586M | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV100463571; called by muse, mutect2, varscan2
- GP2 | c.233A>C p.N78T | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.334); catalogued as COSV100221684; called by muse, mutect2, varscan2
- GPAM | c.1996G>T p.D666Y | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV100788461; called by muse, mutect2, varscan2
- GPAT3 | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as COSV52355595; called by muse, mutect2, varscan2
- GPATCH2L | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.801); catalogued as rs762970587, COSV55047879; called by muse, mutect2, varscan2
- GPER1 | c.1033T>G p.L345V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99867463; called by muse, mutect2, varscan2
- GPR137C | c.640C>A p.L214I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.111); catalogued as COSV100397950; called by muse, mutect2, varscan2
- GPR15 | c.244T>G p.F82V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV99423986; called by muse, mutect2, varscan2
- GPR153 | c.297C>A p.F99L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.754); catalogued as COSV100928629; called by muse, mutect2, varscan2
- GPR174 | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.105); catalogued as rs1489127095, COSV52133424; called by muse, mutect2
- GPR183 | c.866C>A p.S289Y | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1399021903, COSV63117590; called by muse, mutect2, varscan2
- GPRASP1 | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100851095; called by muse, mutect2, varscan2
- GPRASP1 | c.3299C>A p.S1100Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.751); catalogued as COSV100851096; called by muse, mutect2, varscan2
- GRAMD1C | c.1840C>A p.Q614K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV100823038; called by muse, mutect2, varscan2
- GRAP2 | c.542C>T p.S181L | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs865901367, COSV100703187; called by muse, mutect2, varscan2
- GRID2 | c.425A>C p.Y142S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56225636, COSV99947731; called by muse, mutect2, varscan2
- GRIK2 | c.1373G>A p.R458Q | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.792); catalogued as rs760579947, COSV59720927, COSV59731740; called by muse, mutect2, varscan2
- GRIK4 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.955); catalogued as rs780640351, COSV70801363; called by muse, mutect2, varscan2
- GRIN2A | c.1613C>A p.S538* | Nonsense Mutation (SNP) | VAF 5/30 reads (17%) | catalogued as COSV100411265; called by muse, mutect2
- GRK4 | c.249C>A p.F83L (on ENST00000398052 / NM_182982.3; = p.F51L on NM_005307.3) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs142938182; called by muse, mutect2, varscan2
- GRM3 | c.2290A>C p.N764H | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862971; called by muse, mutect2, varscan2
- GRM5 | c.326G>T p.S109I | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100554859, COSV59599374; called by muse, mutect2, varscan2
- GSR | c.1367A>C p.K456T | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV55322051, COSV99645866; called by muse, mutect2, varscan2
- GSTA1 | c.96G>T p.E32D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as COSV100575475; called by muse, mutect2, varscan2
- GSX2 | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV100482542, COSV100482629; called by muse, mutect2, varscan2
- GTF3C3 | c.2572G>T p.D858Y | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV99827092; called by muse, mutect2, varscan2
- GUCY2F | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 10/47 reads (21%) | catalogued as COSV99485779; called by muse, mutect2, varscan2
- GUCY2F | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.223); catalogued as COSV104373270, COSV99485781; called by mutect2, varscan2
- GUCY2F | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.305); catalogued as COSV99485782; called by muse, mutect2
- GXYLT1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.145); catalogued as COSV99789186; called by muse, mutect2, varscan2
- GYG2 | c.547C>A p.L183I | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV100089318; called by muse, mutect2, varscan2
- GYPE | c.221C>A p.S74Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.005); catalogued as COSV100679126, COSV62261477, COSV62261836; called by muse, mutect2, varscan2
- GZMA | c.544C>T p.R182* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | catalogued as rs368948899, COSV57050365; called by muse, mutect2, varscan2
- HACD4 | c.598C>T p.L200F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101530611; called by muse, varscan2
- HACD4 | c.533G>A p.G178D | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.896); catalogued as COSV101530612; called by muse, varscan2
- HAUS6 | c.2578G>A p.E860K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.301); catalogued as rs779630649, COSV100997920; called by muse, mutect2, varscan2
- HCFC1 | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as rs782010359, CM154725, COSV100130039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HCLS1 | c.278G>A p.R93Q | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs770634522, COSV100100281; called by muse, mutect2, varscan2
- HEATR5B | c.334A>C p.K112Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99250372; called by muse, mutect2, varscan2
- HEBP2 | c.405G>T p.M135I | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.09); catalogued as rs749158731, COSV100874960; called by muse, mutect2, varscan2
- HECTD4 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101108412; called by muse, mutect2, varscan2
- HERC2 | c.11791G>A p.E3931K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1161403619, COSV55319355; called by muse, mutect2, varscan2
- HERC4 | c.2266G>T p.E756* (on ENST00000395198 / NM_022079.3; = p.E748* on NM_015601.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV53272008; called by muse, mutect2, varscan2
- HEXB | c.770A>C p.K257T | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs749061539, COSV99784509; called by muse, mutect2, varscan2
- HIPK2 | c.2810C>T p.S937F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.058); catalogued as COSV61233484; called by muse, mutect2, varscan2
- HIVEP2 | c.3106C>T p.P1036S | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99175945; called by muse, mutect2, varscan2
- HMBS | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as COSV99598237; called by muse, mutect2, varscan2
- HMGXB4 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs746800426, COSV53333011; called by muse, mutect2, varscan2
- HOXC13 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99673621; called by muse, mutect2, varscan2
- HROB | c.596A>C p.K199T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV99809449; called by muse, mutect2, varscan2
- HTATSF1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54477300; called by muse, mutect2, varscan2
- HTR1F | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as COSV100138345; called by muse, mutect2, varscan2
- HTT | c.7628T>G p.F2543C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.995); catalogued as COSV100751339; called by muse, mutect2, varscan2
- HUWE1 | c.5162-1G>T p.X1721_splice | Splice Site (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99474604; called by muse, mutect2, varscan2
- IARS1 | c.32T>G p.F11C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100986897; called by muse, mutect2, varscan2
- ICE2 | c.1702C>A p.L568I | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.055); catalogued as COSV55030379; called by muse, mutect2, varscan2
- IFRD1 | c.1174A>C p.N392H | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99134456; called by muse, mutect2, varscan2
- IGF2BP3 | c.781C>A p.L261M | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.081); catalogued as COSV99325945; called by muse, mutect2, varscan2
- IGLV3-25 | c.240C>A p.F80L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); catalogued as rs374596533; called by muse, mutect2, varscan2
- IGSF1 | c.2752C>T p.R918W | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); catalogued as rs201712796, COSV63836956; called by muse, mutect2, varscan2
- IGSF10 | c.4746A>C p.E1582D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV99198719; called by muse, mutect2
- IGSF10 | c.4744G>T p.E1582* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV56790165, COSV99198746; called by muse, mutect2
- IGSF10 | c.1445A>C p.K482T | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV99198772; called by muse, mutect2, varscan2
- IGSF9B | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.793); catalogued as rs1375550934, COSV58066605; called by muse, mutect2, varscan2
- IL10RB | c.235C>A p.L79I | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.134); catalogued as COSV51618560, COSV99270209; called by muse, mutect2, varscan2
- IL1RAPL1 | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | catalogued as COSV100150070; called by muse, mutect2, varscan2
- IL1RAPL2 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV100781913, COSV61160693, COSV61187040; called by muse, mutect2, varscan2
- IL20 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100894173, COSV65584447; called by muse, mutect2, varscan2
- IL21R | c.1580C>T p.P527L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0.058); catalogued as COSV100560652; called by muse, mutect2, varscan2
- IMMP2L | c.398C>A p.S133Y | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.123); catalogued as rs375048435; called by muse, mutect2
- IMPDH2 | c.653T>C p.L218P | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100455228; called by muse, mutect2, varscan2
- IMPG1 | c.777C>A p.Y259* | Nonsense Mutation (SNP) | VAF 7/32 reads (22%) | catalogued as rs569948757, COSV100886744; called by muse, mutect2, varscan2
- INPP5B | c.1889A>C p.K630T (on ENST00000373023; = p.K550T on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65960216; called by muse, mutect2, varscan2
- IRAK3 | c.1580G>T p.R527I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV54159675; called by muse, mutect2, varscan2
- IRX1 | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100116551; called by muse, mutect2, varscan2
- ITIH2 | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as rs765946594, COSV64432356; called by muse, mutect2, varscan2
- ITIH2 | c.2548A>C p.N850H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.909); catalogued as COSV100623465; called by muse, mutect2, varscan2
- ITIH3 | c.577G>T p.G193* | Nonsense Mutation (SNP) | VAF 27/65 reads (42%) | catalogued as COSV101407173; called by muse, mutect2, varscan2
- JAK1 | c.2987C>A p.S996Y | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99037423, COSV99605751; called by muse, mutect2, varscan2
- JAKMIP1 | c.2070G>T p.Q690H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV101290924; called by muse, mutect2, varscan2
- JMJD4 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.158); catalogued as COSV59919812; called by muse, mutect2, varscan2
- KANSL1L | c.464C>A p.S155* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV99911082; called by muse, mutect2, varscan2
- KATNAL2 | c.1006C>T p.R336W (on ENST00000356157 / NM_001353899.1; = p.R264W on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs938926649, COSV55295512; called by muse, mutect2, varscan2
- KATNAL2 | c.1180G>A p.V394I (on ENST00000356157 / NM_001353899.1; = p.V322I on NM_031303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs759070334, COSV99798386; called by muse, mutect2, varscan2
- KATNBL1 | c.63C>A p.F21L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs750048690, COSV99854559; called by muse, mutect2, varscan2
- KCNH4 | c.2307C>A p.F769L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.675); catalogued as COSV99238006; called by mutect2, varscan2
- KCNH7 | c.2410A>C p.K804Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.823); catalogued as COSV100149887; called by muse, mutect2
- KCNH8 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100111155, COSV60477584; called by mutect2, varscan2
- KCNH8 | c.826T>G p.F276V | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100111156; called by muse, mutect2, varscan2
- KCNJ5 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs142140011; called by muse, mutect2, varscan2
- KCNJ6 | c.186G>T p.K62N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99900681; called by mutect2, varscan2
- KCNK10 | c.24C>A p.F8L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59967672; called by muse, mutect2, varscan2
- KCNMB4 | c.437T>G p.F146C | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99253480; called by muse, mutect2, varscan2
- KCNN2 | c.26G>A p.G9D (on ENST00000264773; = p.G221D on NM_021614.4) | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.935); catalogued as rs1452487427, COSV99298472; called by muse, mutect2
- KCNN3 | c.959A>C p.K320T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99679402; called by muse, mutect2, varscan2
- KCNQ5 | c.559C>T p.R187* | Nonsense Mutation (SNP) | VAF 23/76 reads (30%) | catalogued as COSV59652891; called by muse, mutect2, varscan2
- KDM5A | c.3587C>T p.S1196F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV66992217; called by muse, mutect2, varscan2
- KDM6A | c.1447A>C p.N483H | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); catalogued as COSV100938680; called by muse, mutect2, varscan2
- KIAA0319L | c.1822G>T p.E608* | Nonsense Mutation (SNP) | VAF 5/65 reads (8%) | catalogued as COSV100357781; called by muse, mutect2
- KIAA0586 | c.3866T>G p.F1289C (on ENST00000619416 / NM_001244190.2; = p.F1228C on NM_014749.5) | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV99709091; called by muse, mutect2, varscan2
- KIAA1109 | c.11476C>T p.R3826* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99179971; called by muse, mutect2, varscan2
- KIAA1549L | c.1390G>T p.D464Y (on ENST00000321505; = p.D761Y on NM_012194.3) | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); catalogued as COSV99684638; called by mutect2, varscan2
- KIAA1755 | c.1419C>A p.F473L | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV54074902, COSV99642788; called by muse, mutect2, varscan2
- KIDINS220 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs1180977296, COSV56751882; called by muse, mutect2, varscan2
- KIF13A | c.5258C>A p.S1753Y | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.041); catalogued as COSV99438559; called by muse, mutect2, varscan2
- KIF21A | c.4526T>G p.L1509R (on ENST00000361418 / NM_001378440.1; = p.L1496R on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV100735729; called by muse, mutect2, varscan2
- KIF23 | c.304C>A p.H102N | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as COSV99532795; called by muse, mutect2, varscan2
- KIF27 | c.1609A>C p.K537Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV99927340; called by muse, mutect2, varscan2
- KIF4A | c.373G>T p.E125* | Nonsense Mutation (SNP) | VAF 14/51 reads (27%) | catalogued as COSV65542331; called by muse, mutect2, varscan2
- KLHL14 | c.1499G>A p.R500Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.979); catalogued as rs780186069, COSV63833938; called by muse, mutect2, varscan2
- KLHL15 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as rs762473984, COSV100044164, COSV100044467; called by muse, mutect2, varscan2
- KLHL23 | c.1182G>T p.E394D | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV55867043; called by muse, mutect2, varscan2
- KLHL4 | c.339G>T p.K113N | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.017); catalogued as rs186431341, COSV64138698; called by muse, mutect2, varscan2
- KLHL4 | c.2081G>T p.R694I | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as rs745792102, COSV64140751; called by muse, mutect2
- KLHL9 | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 7/19 reads (37%) | catalogued as COSV100757180, COSV62921649; called by muse, mutect2, varscan2
- KLRC2 | c.84A>C p.K28N | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.444); catalogued as COSV101122763, COSV67900105; called by muse, varscan2
- KMT2C | c.7114A>C p.N2372H | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.692); catalogued as COSV100077497; called by muse, mutect2
- KMT2C | c.2498G>T p.R833I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756918375, COSV100077501, COSV51506906; called by muse, mutect2, varscan2
- KMT2E | c.4611A>C p.Q1537H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); catalogued as rs1014680383, COSV99997131; called by muse, mutect2, varscan2
- KNOP1 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV99575397; called by muse, mutect2, varscan2
- KNTC1 | c.4822C>A p.L1608I | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs755131976, COSV61078995; called by muse, mutect2, varscan2
- KRT23 | c.793G>T p.E265* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV99266381; called by muse, mutect2, varscan2
- KRT33A | c.255G>T p.E85D | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as COSV50366112; called by muse, mutect2, varscan2
- KRTAP13-3 | c.289G>T p.V97F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.569); catalogued as COSV100481858; called by muse, mutect2, varscan2
- KTN1 | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV101255482; called by muse, mutect2, varscan2
- LAMA2 | c.5429A>G p.N1810S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV101370669, COSV101370907; called by muse, mutect2, varscan2
- LAMA3 | c.6705G>T p.K2235N (on ENST00000313654 / NM_198129.4; = p.K626N on NM_000227.6) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs372526880; called by muse, varscan2
- LAMB4 | c.1180C>T p.P394S | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); catalogued as COSV52714429; called by muse, mutect2, varscan2
- LAMP3 | c.1244G>T p.R415I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55615819; called by muse, mutect2, varscan2
- LARP4B | c.963G>T p.K321N | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV60220047; called by muse, mutect2, varscan2
- LCA5 | c.1745A>G p.N582S | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.04); catalogued as COSV100878389; called by muse, varscan2
- LEPR | c.3346C>T p.L1116F | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.096); catalogued as COSV100848437; called by muse, varscan2
- LGSN | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); catalogued as rs139295115; called by muse, mutect2, varscan2
- LHX5 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as COSV99922574; called by muse, mutect2, varscan2
- LIPG | c.406A>G p.N136D | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.865); catalogued as COSV99724800; called by muse, mutect2, varscan2
- LMCD1 | c.943A>G p.I315V | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1488470959, COSV99337929; called by muse, mutect2, varscan2
- LMNTD1 | c.943C>A p.L315I | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV51450897; called by muse, mutect2, varscan2
- LMOD2 | c.323G>A p.S108N | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.125); catalogued as COSV101505474; called by muse, mutect2, varscan2
- LMTK3 | c.2645C>T p.A882V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs773623410, COSV99541293; called by muse, mutect2, varscan2
- LNPEP | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.34); catalogued as rs750360079, COSV51476278, COSV51482229; called by muse, mutect2, varscan2
- LONRF3 | c.2113G>A p.A705T (on ENST00000371628 / NM_001031855.3; = p.A664T on NM_024778.5) | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs1360807494, COSV59151335; called by muse, mutect2, varscan2
- LOXL2 | c.2030G>A p.G677D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101207994; called by muse, mutect2, varscan2
- LPAR4 | c.860G>T p.R287I | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.09); catalogued as COSV101425177; called by muse, mutect2, varscan2
- LRCH2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1470042897, COSV57747909; called by muse, mutect2, varscan2
- LRCH4 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.071); catalogued as COSV100053236; called by muse, mutect2, varscan2
- LRFN5 | c.181A>C p.N61H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99985692; called by muse, mutect2, varscan2
- LRGUK | c.1931G>T p.R644I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV53636967, COSV99604777; called by muse, mutect2, varscan2
- LRIG3 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752659488, COSV57860580; called by muse, mutect2, varscan2
- LRIT2 | c.568C>A p.L190I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV100928357; called by muse, mutect2
- LRIT3 | c.1349G>T p.R450I | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.563); catalogued as rs1157741703, COSV59985720, COSV59986898; called by muse, mutect2, varscan2
- LRP1B | c.9516G>T p.K3172N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs775903898, COSV101261831; called by muse, mutect2, varscan2
- LRP1B | c.7327C>T p.R2443C | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774430605, COSV67190954; called by muse, mutect2, varscan2
- LRRC32 | c.1558A>C p.N520H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99477394; called by muse, mutect2, varscan2
- LRRC4B | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as rs779653514, COSV100976068; called by muse, mutect2, varscan2
- LRRC73 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); catalogued as COSV99447644; called by muse, mutect2, varscan2
- LRRC8A | c.1460C>T p.A487V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1225279411, COSV52184092; called by muse, mutect2, varscan2
- LRRK2 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 3/28 reads (11%) | catalogued as COSV54143323; called by muse, mutect2
- LRRTM4 | c.581G>A p.R194Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs747586673, COSV69138794; called by muse, mutect2, varscan2
- LSM12 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as rs779438174, COSV99518671; called by muse, mutect2, varscan2
- LSM2 | c.17T>G p.F6C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100989520; called by muse, mutect2, varscan2
- LZTS1 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56117069; called by muse, mutect2, varscan2
- MACF1 | c.4408C>A p.L1470M | Missense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100483670; called by muse, mutect2, varscan2
- MAGEB10 | c.956G>T p.R319I | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.307); catalogued as COSV100775432; called by muse, mutect2, varscan2
- MAGEC1 | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV99596721; called by muse, mutect2, varscan2
- MAGED1 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100431886; called by muse, mutect2, varscan2
- MAGED2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV54497414; called by muse, mutect2, varscan2
- MAML2 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101594211; called by muse, mutect2, varscan2
- MAN2A2 | c.2942G>T p.R981I | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV100848054, COSV64637381; called by muse, mutect2, varscan2
- MAOB | c.616C>T p.Q206* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV65204455; called by muse, mutect2, varscan2
- MAP2 | c.4492C>A p.H1498N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99561971; called by muse, mutect2, varscan2
- MAP3K13 | c.2870C>T p.T957I | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.897); catalogued as COSV99408126; called by muse, mutect2, varscan2
- MAP3K20 | c.1411A>G p.T471A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100919653; called by muse, mutect2
- MAP7 | c.2092T>G p.L698V | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV100644013; called by muse, mutect2, varscan2
- MARF1 | c.4768G>A p.E1590K | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs374362007; called by muse, mutect2, varscan2
- MASP2 | c.751G>T p.D251Y | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV101280476; called by muse, mutect2, varscan2
- MBD3 | c.448G>T p.D150Y | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99337113; called by mutect2, varscan2
- MCOLN1 | c.1624G>A p.A542T | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.167); catalogued as rs60956953, COSV99654617; called by muse, mutect2, varscan2
- MDGA2 | c.1871G>A p.R624Q (on ENST00000399232 / NM_001113498.2; = p.R326Q on NM_182830.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.531); catalogued as rs553082374, COSV62105261; called by muse, mutect2, varscan2
- MED12L | c.3787G>T p.E1263* | Nonsense Mutation (SNP) | VAF 6/22 reads (27%) | catalogued as rs1347665496, COSV56373981; called by muse, mutect2, varscan2
- MED14 | c.2055A>C p.L685F | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as COSV100247673; called by muse, mutect2, varscan2
- MED23 | c.3773G>T p.R1258I | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645438; called by muse, mutect2
- MED7 | c.242T>G p.L81R | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99644339; called by muse, mutect2, varscan2
- MEI1 | c.181C>T p.R61C | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373855976; called by muse, mutect2, varscan2
- MEIOC | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV100740309, COSV63441606; called by muse, mutect2, varscan2
- MEPE | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs753432480, COSV63072852; called by muse, mutect2
- MIPOL1 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100539732; called by muse, mutect2, varscan2
- MKKS | c.1117T>G p.L373V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.33); catalogued as COSV100726332; called by muse, mutect2, varscan2
- MMAB | c.705G>T p.E235D | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.614); catalogued as COSV57169408; called by muse, mutect2, varscan2
- MMP16 | c.1215C>A p.F405L | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV54181529, COSV99690722; called by muse, mutect2, varscan2
- MMP19 | c.1034G>A p.R345Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as rs762888609, COSV59450393; called by muse, mutect2, varscan2
- MMP3 | c.1331T>G p.F444C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.886); catalogued as COSV100243054; called by muse, mutect2, varscan2
- MOG | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 25/69 reads (36%) | catalogued as rs201832372, COSV65305893; called by muse, mutect2, varscan2
- MORC3 | c.1039A>C p.I347L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV101265085; called by muse, mutect2
- MORN1 | c.108C>A p.F36L | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100088050; called by muse, mutect2, varscan2
- MPEG1 | c.996G>T p.K332N | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99916029; called by muse, mutect2, varscan2
- MPHOSPH10 | c.142G>T p.D48Y | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99731338; called by muse, mutect2, varscan2
- MPO | c.2029C>T p.R677W | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762307268, COSV99229502; called by muse, mutect2, varscan2
- MRPS18B | c.770C>T p.A257V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.243); catalogued as COSV99457966; called by muse, mutect2
- MRPS6 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777690532, COSV100758121; called by muse, mutect2, varscan2
- MSR1 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs200576411, COSV100026618; called by muse, mutect2, varscan2
- MTIF2 | c.1112T>C p.V371A | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV99709394; called by muse, mutect2, varscan2
- MTIF2 | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99709397; called by muse, mutect2, varscan2
- MTM1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs587783861, COSV60333908; ClinVar: benign; called by muse, mutect2, varscan2
- MTMR12 | c.908C>T p.T303I | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99374163; called by muse, mutect2, varscan2
- MTMR8 | c.895G>T p.E299* | Nonsense Mutation (SNP) | VAF 14/71 reads (20%) | catalogued as rs776681861, COSV100878643; called by muse, mutect2, varscan2
- MTRES1 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV100261239; called by muse, mutect2, varscan2
- MTREX | c.1915G>T p.E639* | Nonsense Mutation (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100044620; called by muse, mutect2, varscan2
- MTUS2 | c.1681T>C p.F561L | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV101462394; called by muse, mutect2, varscan2
- MUC15 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.046); catalogued as COSV99846721; called by muse, mutect2, varscan2
- MUC16 | c.26929G>T p.D8977Y | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.808); catalogued as rs775878887, COSV67443634; called by muse, mutect2, varscan2
- MUC16 | c.20213G>A p.R6738Q | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67474551; called by muse, mutect2, varscan2
- MUC17 | c.3050C>A p.S1017Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); catalogued as COSV100075387; called by muse, mutect2, varscan2
- MUC5B | c.4069G>T p.D1357Y | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101500862; called by muse, mutect2, varscan2
- MUC5B | c.5792G>T p.R1931I | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as COSV101500863; called by muse, mutect2, varscan2
- MUC5B | c.9520A>G p.T3174A | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1255697847, COSV101500864; called by muse, mutect2
- MYCBP2 | c.10024G>A p.E3342K (on ENST00000357337; = p.E3380K on NM_015057.5) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV100632223; called by muse, mutect2, varscan2
- MYEF2 | c.454G>T p.E152* | Nonsense Mutation (SNP) | VAF 20/50 reads (40%) | catalogued as COSV99981562; called by muse, mutect2, varscan2
- MYLK | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs1052930526, COSV60610401; called by muse, mutect2, varscan2
- MYO3A | c.945A>C p.E315D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV99781870; called by muse, mutect2, varscan2
- MYOT | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761659382, COSV51801330; ClinVar: uncertain significance; called by mutect2, varscan2
- MYPN | c.1330T>G p.L444V | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.357); catalogued as COSV100589428, COSV100590707; called by muse, mutect2, varscan2
- MYT1 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.005); catalogued as COSV60503009; called by muse, mutect2, varscan2
- NAA15 | c.1645C>T p.R549* | Nonsense Mutation (SNP) | VAF 4/24 reads (17%) | catalogued as rs1179904078, COSV56718173; called by mutect2, varscan2
- NAB1 | c.81T>G p.F27L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100493187; called by muse, mutect2, varscan2
- NAPG | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.414); catalogued as COSV59796754; called by muse, mutect2, varscan2
- NAV2 | c.4029A>C p.K1343N (on ENST00000396087 / NM_001244963.2; = p.K1320N on NM_145117.5) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV100217749; called by muse, mutect2, varscan2
- NBEA | c.643A>C p.K215Q | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1196982174, COSV100084835; called by muse, mutect2
- NBEA | c.1392G>T p.E464D | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100084839, COSV59790289; called by muse, mutect2, varscan2
- NCAM2 | c.303A>C p.Q101H | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV99525667; called by muse, mutect2
- NCAM2 | c.2409G>T p.L803F | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.997); catalogued as COSV99525671; called by muse, mutect2, varscan2
- NCAPD3 | c.3203A>C p.K1068T | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV101594461, COSV73244836; called by muse, mutect2, varscan2
- NCOA6 | c.5293G>T p.E1765* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV62861677; called by muse, mutect2, varscan2
- NCOR1 | c.1073G>T p.R358I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51968546; called by muse, mutect2
- NDNF | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | catalogued as rs745563516, COSV65633523; called by muse, mutect2, varscan2
- NDRG3 | c.910G>A p.E304K (on ENST00000349004 / NM_032013.4; = p.E292K on NM_022477.4) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372522320; called by muse, mutect2, varscan2
- NDUFB11 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.3); PolyPhen benign (0.072); catalogued as COSV52101786, COSV52102957; called by muse, mutect2
- NEK10 | c.1756A>G p.N586D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.422); catalogued as COSV100412384; called by muse, mutect2, varscan2
- NEK2 | c.585G>T p.E195D | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV100878794; called by muse, mutect2, varscan2
- NETO1 | c.1120C>T p.Q374* | Nonsense Mutation (SNP) | VAF 13/50 reads (26%) | catalogued as COSV100199870; called by muse, mutect2, varscan2
- NF1 | c.7915C>A p.L2639I (on ENST00000358273 / NM_001042492.3; = p.L2618I on NM_000267.3) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62195613; called by muse, mutect2, varscan2
- NFASC | c.76G>A p.E26K | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1313443406, COSV100362558; called by muse, mutect2, varscan2
- NFAT5 | c.1142+1G>A p.X381_splice | Splice Site (SNP) | VAF 13/42 reads (31%) | catalogued as COSV63025519; called by muse, mutect2, varscan2
- NFS1 | c.874C>T p.R292W | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866522271, COSV100932027; called by muse, mutect2, varscan2
- NHS | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101197048; called by muse, mutect2, varscan2
- NIF3L1 | c.344G>T p.R115L (on ENST00000409020 / NM_001369444.1; = p.R88L on NM_021824.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV99627022; called by muse, varscan2
- NIPBL | c.4994C>G p.T1665S | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as COSV99243022; called by muse, mutect2, varscan2
- NLGN4X | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV52008892; called by muse, mutect2, varscan2
- NLRP13 | c.391A>G p.N131D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV100738607; called by muse, mutect2, varscan2
- NLRP5 | c.2060C>T p.A687V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.392); catalogued as COSV101173928; called by muse, mutect2, varscan2
- NLRP5 | c.2998C>T p.L1000F | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101173929; called by muse, mutect2, varscan2
- NLRP9 | c.1279A>G p.M427V | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.93); PolyPhen benign (0.003); catalogued as rs1480834494, COSV100243566; called by muse, mutect2, varscan2
- NOA1 | c.1580G>T p.R527I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51738725, COSV99950729; called by muse, mutect2, varscan2
- NOC2L | c.1996G>T p.D666Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV100498213; called by muse, mutect2, varscan2
- NOS1AP | c.414C>A p.S138R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100723079, COSV100723685; called by mutect2, varscan2
- NOTCH4 | c.4837C>T p.P1613S | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV100901159; called by muse, mutect2, varscan2
- NOVA1 | c.155T>A p.L52Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV99948910; called by muse, mutect2
- NOX1 | c.1331C>T p.A444V | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99471774; called by muse, mutect2, varscan2
- NPAS2 | c.364T>G p.S122A | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100177109; called by muse, mutect2, varscan2
- NPAT | c.806A>C p.K269T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53721539; called by muse, mutect2
- NPC1L1 | c.939A>C p.K313N | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.072); catalogued as COSV99213702; called by muse, mutect2
- NPSR1 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.747); catalogued as rs375118842, COSV100706872; called by muse, mutect2, varscan2
- NPY5R | c.1073G>T p.R358I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV100642971; called by muse, mutect2, varscan2
- NRDE2 | c.1328A>C p.K443T | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100583692; called by muse, mutect2, varscan2
- NRG3 | c.1663T>C p.S555P (on ENST00000404547 / NM_001370084.1; = p.S531P on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.387); catalogued as COSV100932660; called by muse, mutect2, varscan2
- NRP2 | c.29T>G p.F10C | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as COSV99785914; called by muse, mutect2, varscan2
- NRP2 | c.2132G>A p.R711Q | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.994); catalogued as rs755747845, COSV99785917; called by muse, mutect2, varscan2
- NRXN2 | c.5112G>T p.K1704N | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV55457511; called by muse, mutect2, varscan2
- NRXN2 | c.4242G>T p.E1414D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV99636182; called by muse, mutect2, varscan2
- NRXN2 | c.1854G>T p.E618D | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as COSV99636185; called by muse, mutect2, varscan2
- NT5C1B | c.1721T>G p.L574W (on ENST00000359846 / NM_001199086.2; = p.L514W on NM_033253.4) | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100410324; called by muse, mutect2, varscan2
- NUCB2 | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 6/12 reads (50%) | catalogued as COSV60374252, COSV60376135; called by muse, mutect2, varscan2
- NUMB | c.1238C>T p.S413L (on ENST00000355058; = p.S402L on NM_003744.5) | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs771373657, COSV61572240; called by muse, mutect2, varscan2
- NUP107 | c.2097C>A p.F699L | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs764792538, COSV57498340; called by muse, mutect2
- NUP50 | c.1201T>G p.L401V | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as COSV100754425; called by muse, mutect2, varscan2
- NXPE1 | c.1015A>G p.K339E (on ENST00000424269; = p.K197E on NM_152315.5) | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV99321156; called by muse, mutect2, varscan2
- NXPE3 | c.1070A>G p.H357R | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as rs1560065534, COSV99840239; called by muse, mutect2, varscan2
- NXPH3 | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.011); catalogued as COSV100165601; called by muse, mutect2, varscan2
- OBSCN | c.3905C>T p.S1302L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.617); catalogued as rs1222359446, COSV52745504; called by muse, mutect2, varscan2
- OR10K2 | c.278C>A p.S93Y | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV59220831, COSV59221326; called by muse, mutect2, varscan2
- OR10X1 | c.27C>A p.F9L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as COSV100936719; called by muse, mutect2
- OR2AE1 | c.55G>T p.D19Y | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100318438, COSV60389946; called by muse, mutect2, varscan2
- OR4C12 | c.620T>C p.L207S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV100078724; called by muse, mutect2, varscan2
- OR4C13 | c.609C>A p.F203L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV101634247; called by muse, varscan2
- OR4C13 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.598); catalogued as COSV101634196, COSV101634248; called by muse, varscan2
- OR4C15 | c.6C>A p.F2L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV100116172; called by muse, mutect2, varscan2
- OR4M1 | c.255C>A p.F85L | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.021); catalogued as COSV100271448, COSV60059940; called by muse, mutect2, varscan2
- OR4X2 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100183358; called by muse, mutect2, varscan2
- OR51A2 | c.667C>A p.L223I | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as COSV100985103, COSV66748189, COSV66748257; called by muse, mutect2
- OR52B4 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs760879031, COSV101281611, COSV101281616; called by muse, mutect2, varscan2
- OR52E6 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as rs1336454727, COSV100259574, COSV100259581; called by muse, mutect2, varscan2
- OR5B17 | c.900G>T p.M300I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100641973; called by muse, mutect2
- OR5D14 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.229); catalogued as rs529138416, COSV59458174; called by muse, mutect2, varscan2
- OR5D16 | c.17G>T p.R6I | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV65722353; called by muse, mutect2, varscan2
- OR5F1 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53546525, COSV99558988; called by muse, mutect2, varscan2
- OR5F1 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs190524347, COSV53546231; called by muse, mutect2, varscan2
- OR5R1 | c.281T>G p.F94C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV100393618; called by muse, mutect2, varscan2
- OR5T3 | c.696C>A p.F232L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV100282735, COSV100282964; called by muse, mutect2, varscan2
- OR5V1 | c.18A>C p.Q6H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV101011501; called by muse, mutect2, varscan2
- OR6C6 | c.565G>T p.D189Y | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV100626536; called by muse, mutect2, varscan2
- OR8I2 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as COSV100136279, COSV56169150; called by muse, mutect2, varscan2
- OR8J1 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.905); catalogued as COSV57317713, COSV57317992; called by muse, mutect2, varscan2
- ORC1 | c.242A>C p.K81T | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV100856772; called by muse, mutect2, varscan2
- OVCH1 | c.2471A>G p.K824R | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.811); catalogued as COSV100549311; called by muse, mutect2, varscan2
- OXR1 | c.2113C>T p.R705* (on ENST00000442977 / NM_001198532.1; = p.R677* on NM_018002.3) | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as rs267601704, COSV52427812; called by muse, mutect2, varscan2
- PA2G4 | c.728G>T p.R243I | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100306508, COSV57568316; called by muse, mutect2, varscan2
- PAH | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100188483; called by muse, mutect2, varscan2
- PAK2 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100506409; called by muse, mutect2, varscan2
- PAPOLG | c.1634C>A p.S545Y | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99475086; called by muse, mutect2, varscan2
- PAPPA | c.3077A>C p.N1026T | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.031); catalogued as COSV100075560; called by muse, mutect2, varscan2
- PARP14 | c.5283G>T p.K1761N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101506239, COSV101506367; called by muse, mutect2, varscan2
- PARP6 | c.556T>G p.F186V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99536433; called by muse, mutect2, varscan2
- PARPBP | c.664T>G p.L222V | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV100569330; called by muse, mutect2, varscan2
- PATJ | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs375548878; called by muse, mutect2, varscan2
- PAX5 | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.969); catalogued as COSV100814664; called by muse, mutect2, varscan2
- PBRM1 | c.3688C>A p.L1230I (on ENST00000296302 / NM_001366071.2; = p.L1205I on NM_018313.5) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.81); PolyPhen benign (0.096); catalogued as COSV99971256; called by muse, mutect2, varscan2
- PCDH15 | c.5671G>T p.E1891* | Nonsense Mutation (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100228578; called by muse, mutect2, varscan2
- PCDH17 | c.3421G>T p.E1141* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV64978776; called by muse, mutect2, varscan2
- PCDH19 | c.1471C>A p.Q491K | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV99720940; called by muse, mutect2, varscan2
- PCDHAC1 | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.033); catalogued as COSV53873233; called by muse, mutect2
- PCDHAC1 | c.2246G>T p.R749I | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV53836597; called by muse, mutect2, varscan2
- PCDHB1 | c.922G>A p.D308N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.948); catalogued as rs782642827, COSV60630574; called by muse, mutect2, varscan2
- PCDHB11 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV61310480, COSV61312804; called by muse, mutect2, varscan2
- PCDHGA3 | c.841C>A p.L281I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.06); catalogued as COSV54019731, COSV99548523; called by muse, mutect2
- PCDHGB1 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.62); catalogued as COSV99548526; called by muse, mutect2, varscan2
- PCGF5 | c.627C>A p.F209L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60239011; called by muse, mutect2, varscan2
- PCMTD2 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.722); catalogued as rs1281143796, COSV100204359; called by muse, mutect2, varscan2
- PCSK6 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs563861296, COSV59340826; called by muse, mutect2, varscan2
- PDCD2L | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.147); catalogued as rs372971197; called by muse, mutect2, varscan2
- PDE11A | c.1028A>C p.N343T | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99615493; called by muse, mutect2, varscan2
- PDE4A | c.552G>T p.V184= | Splice Region (SNP) | VAF 10/28 reads (36%) | catalogued as COSV99535365; called by muse, mutect2, varscan2
- PDE6A | c.1709C>T p.T570I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.25); catalogued as COSV99678786; called by muse, mutect2, varscan2
- PDGFB | c.677T>G p.F226C | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as COSV100483611; called by muse, mutect2
- PDHA1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100135915; called by muse, mutect2, varscan2
- PDS5B | c.1988C>A p.S663* | Nonsense Mutation (SNP) | VAF 5/42 reads (12%) | catalogued as COSV100221621; called by muse, mutect2, varscan2
- PDZD3 | c.1693G>A p.A565T (on ENST00000531114; = p.A485T on NM_024791.4) | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as COSV100501626; called by muse, mutect2, varscan2
- PDZRN4 | c.898C>T p.R300C (on ENST00000402685 / NM_001164595.2; = p.R42C on NM_013377.4) | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs919511511, COSV54197322; called by muse, mutect2, varscan2
- PEG3 | c.2050C>T p.L684F | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.041); catalogued as rs1169442588, COSV99690683; called by muse, mutect2, varscan2
- PER2 | c.1613A>C p.K538T | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV99612674; called by muse, mutect2, varscan2
- PFAS | c.3690G>T p.W1230C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100119201; called by muse, mutect2, varscan2
- PFKP | c.1313C>T p.A438V | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as COSV101127575; called by muse, mutect2, varscan2
- PGLYRP1 | c.179C>T p.S60L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.973); catalogued as rs1011946937, COSV99151540; called by muse, mutect2, varscan2
- PGM2 | c.1621A>C p.S541R | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV101126670; called by muse, mutect2, varscan2
- PHACTR4 | c.386T>G p.L129* (on ENST00000373839 / NM_001350159.2; = p.L139* on NM_023923.4) | Nonsense Mutation (SNP) | VAF 11/33 reads (33%) | catalogued as COSV100868505; called by muse, mutect2, varscan2
- PHF23 | c.1060A>G p.I354V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99138939; called by muse, mutect2, varscan2
- PHKA2 | c.3052G>A p.E1018K | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV66052921; called by muse, mutect2
- PHKB | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV100068766; called by muse, mutect2, varscan2
- PHKB | c.947C>G p.T316R | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100068773; called by muse, mutect2, varscan2
- PHTF2 | c.2051T>G p.F684C (on ENST00000248550 / NM_001366089.1; = p.F646C on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99302476; called by muse, mutect2, varscan2
- PIAS2 | c.200G>A p.R67Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as rs775760594, COSV61344413; called by muse, mutect2, varscan2
- PIGM | c.934G>T p.D312Y | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100928022; called by muse, mutect2, varscan2
736 further variants in this file (437 protein-altering or splice-affecting, 261 silent, 38 other) are not listed here.
